Gene-level copy-number profile of tumor specimen ALCH-AD6R-TTP1-A from ALCHEMIST case ALCH-AD6R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.8 years (20,010 days).
Specimen ALCH-AD6R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b2a4e85a-ea68-4753-be2b-53158f9d3fab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD6R-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/92daf5cf-2028-41ad-ae88-cd668fc7b626

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 8,372; copy number 2: 46,387; copy number 3: 4,099; copy number 4: 7; copy number 5: 5; copy number 6: 2; copy number 8: 1; copy number 12: 1; copy number 32: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,144,056, 1 gene: LINC01342.
- chr1:1,211,340–1,292,029, 8 genes: TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D.
- chr22:21,290,760–21,325,042, 3 genes (within-gene range 0–5): BCRP6, FAM230H, AP000552.2.
- chr22:21,379,382–21,396,590, 5 genes: Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,203,508–1,206,592, 1 gene, copy number 5: TNFRSF18.
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr21:13,525,599–13,528,579, 1 gene, copy number 5: SNX19P1.
- chr22:18,873,543–18,894,407, 2 genes, copy number 6: FAM230F, AC008103.1.
- chr22:21,125,660–21,128,063, 1 gene, copy number 12: POM121L7P.
- chr22:21,193,360–21,203,755, 1 gene, copy number 5: FAM247A.
- chr22:21,228,760–21,229,138, 1 gene, copy number 5: AP000550.3.
- chr22:21,341,595–21,345,258, 1 gene, copy number 8: PPP1R26P5.
- chr22:21,370,064–21,371,945, 1 gene, copy number 32: AP000552.1.

Autosomal genes at a single copy (total copy number 1): 5,535. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
